Gene-level copy-number profile of tumor specimen TCGA-D1-A168-01A from TCGA case TCGA-D1-A168, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 67.3 years (24,586 days).
Specimen TCGA-D1-A168-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.4f0555c2-45e5-4459-af6b-db805ab171bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A168-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb11d904-b182-49bc-b8d9-cdc16acc3b1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 156; copy number 2: 44,737; copy number 3: 12,113; copy number 5: 2,814.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-D1-A168-01): tumor purity 0.85, ploidy 2.29, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,814 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–198,222,513, 1,483 genes, copy number 5 (broad region; genes not listed).
- chr16:11,555–34,142,849, 1,331 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
